TCGA case TCGA-D3-A3ML — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0153f141-625e-4623-9f8a-296678002c63

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 70 years; Vital status: Dead; Days to death: 422 days (1.2 years).

Diagnoses (10; GDC holds 11 diagnosis records for this case, 1 of them empty or duplicates of those shown)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.0; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: Progression; Age at diagnosis: 70.8 years (25,873 days); Days to diagnosis: 230 days; Prior treatment: Yes.
   Treatment given: Treatment type: Chemotherapy; Timepoint category: Prior to Procurement.
   Recorded as not given: Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: IV; Sites of involvement: Skin, Head and Neck; Ulceration indicator: No.
   Pathology details: Breslow thickness category: >2.0-4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 70.2 years (25,643 days); Year of diagnosis: 2003; AJCC staging edition: 7th; AJCC pathologic T: T3a; AJCC pathologic N: N2a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: Yes; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 264 days; Days to treatment end: 278 days; Treatment dose: 30 Gy; Treatment outcome: Progressive Disease; Number of fractions: 5; Treatment anatomic sites: Regional Site.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
4. Basal cell carcinoma, NOS: ICD-O-3 morphology code: 8090/3; Classification of tumor: Prior primary.
5. Fibrosarcoma, NOS: ICD-O-3 morphology code: 8810/3; Tissue or organ of origin: Pelvis, NOS; Laterality: Left; Classification of tumor: Prior primary.
6. Metastasis of diagnosis 4 (Malignant melanoma, NOS), site: Lymph node, NOS. Age at diagnosis: 70.3 years (25,675 days); Days to diagnosis: 32 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 54 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease.
7. Mycosis fungoides: ICD-O-3 morphology code: 9700/3; Classification of tumor: Subsequent Primary; Age at diagnosis: 70.3 years (25,676 days); Days to diagnosis: 33 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: Radiation Therapy, NOS, for initial diagnosis; Surgery, NOS, for initial diagnosis.
8. Metastasis of diagnosis 4 (Malignant melanoma, NOS), site: Lymph node, NOS. Age at diagnosis: 70.6 years (25,798 days); Days to diagnosis: 155 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 187 days.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
9. Metastasis of diagnosis 4 (Malignant melanoma, NOS), site: Peritoneum, NOS. Age at diagnosis: 71.3 years (26,029 days); Days to diagnosis: 386 days (1.1 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
10. Metastasis of diagnosis 4 (Malignant melanoma, NOS), site: Spleen. Age at diagnosis: 71.3 years (26,029 days); Days to diagnosis: 386 days (1.1 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (5 entries)
- Day 32 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 32 days.
- Day 155 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 155 days.
- Day 386 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Spleen; Days to progression: 386 days (1.1 years).
- Day 386 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Peritoneum, NOS; Days to progression: 386 days (1.1 years).
- Days to follow up: 422 days (1.2 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 3.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 76 kg; Height: 178 cm; BMI: 24.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D3-A3ML-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 120 mg.
  Slide TCGA-D3-A3ML-06A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-D3-A3ML-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: Yes; Tumor status: With tumor; Breslow thickness at diagnosis: 2.3; Primary melanoma tumor ulceration: No; Primary melanoma mitotic rate: 3; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: Yes.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Head and Neck; Melanoma primary count: 1.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Face & Trunk; Other malignancy histological type: Basal Cell Carcinoma.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Prostate cancer.
- Other malignancy form 3: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Groin; Other malignancy histological type: Fibrosarcoma.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: systemic treatment.
- Prior malignancy: Patient had a fibrosarcoma of the groin, basal cell carcinoma of the face and trunk, and prostate carcinoma. No radiation or systemic chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 422 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 422 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 32 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D3-A3ML-06A-11D-A219-01): tumor purity 0.97, ploidy 2.23, whole-genome doublings 0.
